Gene-level copy-number profile of tumor specimen TCGA-18-4721-01A from TCGA case TCGA-18-4721, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.1 years (27,076 days).
Specimen TCGA-18-4721-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d506ae16-54a5-469d-838e-5b4b9579d28b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-4721-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ccaadac-fee7-46ca-ad83-ed373ec75c20

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 23,631; copy number 2: 31,719; copy number 3: 3,809; copy number 4: 179; copy number 5: 130; copy number 6: 60; copy number 10: 265.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-4721-01A-01D-1439-01): tumor purity 0.39, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:97,077,743–97,995,000, 5 genes (within-gene range 0–1): DPYD, DPYD-AS1, DPYD-IT1, SEC63P1, RPL26P9.
- chr9:14,475–492,248, 12 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1.
- chr9:477,750–558,930, 4 genes: RPL12P25, AL161725.2, AL392089.1, RNU6-1327P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 455 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:166,181,313–185,052,614, 325 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr4:45,323,253–48,780,322, 38 genes, copy number 5: THAP12P9, AC108043.1, RNU6-931P, RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P.
- chr8:36,987,977–40,520,158, 90 genes, copy number 5 (broad region; genes not listed).
- chr18:79,959,579–79,970,822, 2 genes, copy number 5: AC114341.2, HSBP1L1.

Autosomal genes at a single copy (total copy number 1): 21,210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
